Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8164, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8164-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Patient Name: [REDACTED]

Med: Rec.: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Accession #: [REDACTED]

Phone Number: [REDACTED]

Gender: M

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

CLINICAL HISTORY

Right frontal tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, right frontal tumor, excision biopsy: Oligodendroglioma,
WHO Grade
II (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis of low-grade oligodendroglioma. The tumor shows focal moderately dense cellularity however mitotic activity, microvascular proliferation and necrosis are not seen.

Cerebral cortex calcospherites are noted.

Results of ancillary studies will be reported below in procedure addenda.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

[page 2 of 4]
H slide was examined and no microdissection was needed

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Loss of Heterozygosity 1p, 19q Assay (LOH)
Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p is detected.
Changes suggestive of partial deletion of chromosome arm 19q (D19S219, D19S606-deleted; PLA2G4C-not deleted)

Informative loci are: D1S552, D1S1612, D19S219, D19S606, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
DNA extracted from a corresponding blood specimen was used as a normal reference control.

[page 3 of 4]
H slide was examined and no microdissection was needed

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA ' 88 regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

[REDACTED]
IDH1/IDH2 Mutation Detection Assay

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

The R132H IDH1 mutation was detected by monoclonal antibody and confirmed by

PCR. These tests are currently experimental in this laboratory.

Results-Comments

IDH1 mutation was tested by immunostaining and molecular analysis.

Electronically Signed Out

[page 4 of 4]
INTRA-OPERATIVE CONSULTATION

A. Brain, right frontal tumor, biopsy: Astrogliosis and atypical glial proliferation consistent with low-grade glioma (oligodendroglioma). Intraoperative frozen section and smears performed at [REDACTED] and [REDACTED] results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A. Brain tumor, biopsy: received fresh and labeled "Brain tumor" are multiple fragments of soft tan-grey tissue, approximately 4 cm in aggregate.

A portion has been submitted for frozen section analysis, while the remaining tissue has been sectioned by pathologist and submitted for routine examination in blocks 2-4.

SECTIONS:

1 Frozen Section remnant
2-4 remaining tissue. 4-NS

ICD-9(s):

191.9 191.9

Histo Data

Part A: Brain tumor, biopsy

Taken:	Received:	
Stain/	Block	Ordered
FS H/E x 1	1	
H/E x 1	1	
TPS H/E x 1	1	
H/E x 1	2	
H/E x 1	3	
H/E x 1	4	
LOH-curles x 1	4	
MGMT-curles x 1	4	
MIB1-DA x 1	4	
IDH1. Ask		
KR.		
Rct 1 H/E x 1	4	

*** End of Report ***

Please also run

Source: NCI Genomic Data Commons file a13ac203-ee2a-4dae-843f-77d0b44e5d9f (TCGA-DU-8164.452CB553-EE9B-44E3-BBC4-FCB36F015309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).